Somatic mutation profile of tumor specimen TCGA-DX-A7EU-01A (aliquot TCGA-DX-A7EU-01A-22D-A36J-09) from TCGA case TCGA-DX-A7EU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 80.0 years (29,211 days).
Specimen TCGA-DX-A7EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3e69ace-0952-4233-9eb7-3f3ce7eb7fa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EU-10A (Blood Derived Normal), aliquot TCGA-DX-A7EU-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/131b5c11-0289-4eb0-8bab-dd78b8c9dc3b

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 11, 5'Flank 2, 3'UTR 1, Intron 1, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 26/34 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.143T>C p.F48S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99792835; called by muse, mutect2
- ABCC8 | c.3344C>T p.T1115M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764051832, COSV100217414, COSV56848319; called by muse, mutect2, varscan2
- ACAN | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs369608360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL1 | c.3040G>C p.V1014L (on ENST00000340736 / NM_001008701.3; = p.V1009L on NM_014921.5) | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV100529767; called by muse, varscan2
- ADRM1 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.342); catalogued as COSV99445797; called by muse, mutect2
- AGAP2 | c.2470C>T p.P824S (on ENST00000547588 / NM_001122772.2; = p.P488S on NM_014770.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV99224095; called by muse, mutect2, varscan2
- C20orf194 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99331390; called by muse, mutect2
- CD300C | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs201444602; called by muse, mutect2, varscan2
- CD300LB | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100075566; called by muse, mutect2, varscan2
- CDC42BPG | c.4364G>A p.R1455Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV61348793; called by muse, mutect2, varscan2
- CDH20 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV99406382; called by muse, mutect2, varscan2
- CHD5 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs1200082377, COSV99314393; called by mutect2, varscan2
- COG2 | c.898A>G p.S300G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.112); catalogued as COSV64186755; called by muse, mutect2, varscan2
- DAB1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs774168195, COSV59722038; called by muse, mutect2, varscan2
- DPY19L2 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs747152353, COSV100193956; called by muse, mutect2, varscan2
- DTX1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1264108701, COSV57501074, COSV57502052; called by muse, mutect2
- ELAVL3 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1334554298, COSV99371893; called by muse, mutect2, varscan2
- FN3K | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs779354525, COSV100333365; called by muse, mutect2, varscan2
- FRRS1 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as rs774713001, COSV54921881; called by muse, mutect2, varscan2
- GET1 | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV100414429, COSV61554982; called by muse, mutect2, varscan2
- GGN | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.88); catalogued as rs1476347261, COSV99287653; called by muse, mutect2
- GPR182 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as rs546209144, COSV55627059; called by muse, mutect2, varscan2
- HELZ2 | c.5069C>T p.A1690V (on ENST00000467148 / NM_001037335.2; = p.A1121V on NM_033405.3) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs774013881, COSV71296273; called by muse, mutect2, varscan2
- JAKMIP3 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770407014, COSV100059801; called by muse, mutect2, varscan2
- JPH1 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV60611831; called by muse, mutect2
- KCNT2 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs200217178; called by muse, mutect2, varscan2
- KCNV2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs746359393, COSV101172609, COSV66057010; called by muse, mutect2, varscan2
- KHDRBS2 | c.629T>A p.I210N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as COSV99836864; called by muse, mutect2, varscan2
- MFSD6L | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100266814; called by mutect2, varscan2
- MUC6 | c.5278G>A p.E1760K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated, low confidence (0.82); PolyPhen possibly damaging (0.901); catalogued as COSV101424754; called by muse, mutect2
- MYO5A | c.1341T>A p.N447K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100698073; called by muse, mutect2
- NLRP4 | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV56717239; called by muse, mutect2, varscan2
- NRDC | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.086); catalogued as COSV100703770; called by muse, mutect2
- OR1S1 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.112); catalogued as COSV100515480; called by muse, mutect2
- PATZ1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as rs994508743, COSV56743457; called by muse, mutect2
- PCDHB7 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.187); catalogued as COSV50757097, COSV50774573; called by muse, mutect2
- PELI3 | c.1265G>A p.C422Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100291891; called by muse, mutect2, varscan2
- PIP5KL1 | c.1148G>A p.R383H (on ENST00000388747 / NM_001135219.2; = p.R180H on NM_173492.1) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1314150285, COSV100231593, COSV55944669; called by muse, varscan2
- PLG | c.797C>A p.P266Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV99805043; called by muse, mutect2, varscan2
- RIMBP2 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.546); catalogued as rs147881182; called by muse, mutect2, varscan2
- SFMBT2 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs774454869, COSV100739548; called by muse, mutect2, varscan2
- SLC38A4 | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56966893; called by muse, mutect2, varscan2
- SOX14 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV100048317; called by muse, mutect2, varscan2
- USP18 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs373096161, COSV99306209; called by muse, mutect2, varscan2
- WDR45 | c.941G>A p.R314H (on ENST00000376372 / NM_001029896.2; = p.R315H on NM_007075.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs782736017, COSV59875954; called by muse, varscan2
- ZBTB22 | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99802570; called by muse, mutect2
- ZNF697 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs959491295, COSV101360297; called by muse, mutect2, varscan2
- ATRX | c.5561dup p.L1854Ffs*7 | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- CHD9 | c.5214A>C p.K1738N | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- PRAMEF10 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.328); called by muse, mutect2
- ARSL | c.948C>T p.H316= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV66966290; called by muse, mutect2, varscan2
- C2CD3 | c.2295C>T p.L765= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs757665195, COSV58099867; called by muse, mutect2, varscan2
- CCDC105 | c.1020G>A p.A340= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1411876478, COSV99480088; called by muse, mutect2, varscan2
- FBN3 | c.8112C>T p.S2704= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs967738909, COSV99495238; called by muse, mutect2, varscan2
- HOOK2 | c.1959A>G p.R653= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99317811; called by muse, mutect2, varscan2
- INCENP | c.828A>G p.P276= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs771395555, COSV99611407; called by muse, mutect2, varscan2
- PAEP | c.441C>T p.D147= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs759775076, COSV99478997; called by mutect2, varscan2
- PELI3 | c.948G>A p.K316= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100291888; called by muse, mutect2
- PKHD1L1 | c.5244T>C p.T1748= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV101006721; called by muse, mutect2
- SLIT2 | c.1200T>C p.L400= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99886703; called by muse, mutect2, varscan2
- WRN | c.3894C>G p.G1298= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99989729; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824175 G>T | 5'Flank (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- CCSER1 | c.2094+23067G>A | Intron (SNP) | VAF 14/204 reads (7%) | catalogued as rs758881469; called by muse, mutect2
- DCHS2 | n.3366G>A | RNA (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- SLC5A1 | chr22:32039602 C>T | 5'Flank (SNP) | VAF 10/102 reads (10%) | catalogued as rs1026029841; called by muse, mutect2
- UVSSA | c.*8989G>A | 3'UTR (SNP) | VAF 10/106 reads (9%) | catalogued as rs146777511; called by muse, varscan2
